Somatic mutation profile of tumor specimen BA3411D (aliquot aq-BA3411D) from BEATAML1.0 case 2615, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.7 years (17,785 days).
Specimen BA3411D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f41f76f7-c938-4f64-88a7-c6df4462be8a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3188D (Solid Tissue Normal), aliquot aq-BA3188D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0383fa1c-6d54-411b-bd77-176ac3f36d58

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAG2 | c.1196+2T>G p.X399_splice | Splice Site (SNP) | VAF 32/94 reads (34%) | catalogued as COSV54366681; called by muse, mutect2, varscan2
- TMCO3 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767346294; called by muse, mutect2
- U2AF2 | c.572_586del p.I191_K195del | In Frame Del (DEL) | VAF 21/56 reads (38%) | called by mutect2, pindel, varscan2
